Gene-level copy-number profile of specimen HCM-WCMC-0789-C34-85A from HCMI case HCM-WCMC-0789-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G2; Age at diagnosis: 83.6 years (30,550 days).
Specimen HCM-WCMC-0789-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 11.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d9155861-2f15-4cbe-b1ac-39817e4b205e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0789-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/dacb4984-a90a-486f-b185-ffb171e5a308

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,955; copy number 2: 41,356; copy number 3: 11,337; copy number 4: 1,021; copy number 5: 420; copy number 6: 208; copy number 7: 515; copy number 8: 4; copy number 12: 70.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,217 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:148,772,640–148,796,325, 2 genes, copy number 12: SEC22B3P, AC245389.1.
- chr1:200,739,558–201,469,237, 22 genes, copy number 5: CAMSAP2, RPL34P6, GPR25, INAVA, MROH3P, RNU6-704P, KIF21B, AL358473.1, AL358473.2, CACNA1S, ASCL5, TMEM9, IGFN1, AC103925.1, PKP1, TNNT2, AC119427.2, LAD1, TNNI1, AC096677.3, PHLDA3, AC096677.2.
- chr1:206,747,980–207,879,115, 35 genes, copy number 5 (within-gene range 3–5): Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55, CR2, CR1, AL137789.1, CR1L, CD46P1, CDCA4P3, RNA5SP534, AL137789.2, CD46, CDCA4P4, MIR29B2CHG, MIR29C, MIR29B2.
- chr1:216,503,246–223,950,416, 109 genes, copy number 5–6 (broad region; genes not listed).
- chr1:224,717,504–234,324,511, 229 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr1:244,352,635–248,565,299, 136 genes, copy number 5–12 (broad region; genes not listed).
- chr1:248,649,838–248,937,043, 16 genes, copy number 6: OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr8:9,555,912–10,859,436, 30 genes, copy number 5 (within-gene range 3–5): TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1, AC112673.1, AC104964.2, LINCR-0001, PRSS52P, RNU6-729P, AC104964.1, PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2.
- chr8:31,275,542–31,390,805, 2 genes, copy number 5: AC068672.2, AC068672.3.
- chr8:78,268,637–78,558,503, 1 gene, copy number 5 (within-gene range 4–5): PKIA-AS1.
- chr8:78,516,340–78,956,082, 8 genes, copy number 5–6: PKIA, AC068700.1, ZC2HC1A, IL7, AC100854.1, THAP12P7, AC083837.1, LINC02605.
- chr8:101,287,445–104,256,094, 67 genes, copy number 5 (broad region; genes not listed).
- chr8:105,929,126–145,066,685, 560 genes, copy number 5–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,099. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
